Surgical pathology report (de-identified scan), TCGA case TCGA-PC-A5DM, project TCGA-SARC (Sarcoma), tissue source site Fox Chase, specimen TCGA-PC-A5DM-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN:
SURGICAL PATHOLOGY REPORT

DOE
Sex: M
Location:
Date Collected:
Date Received:
Physician:
Copy To:
Clinical History/Diagnosis: Left thigh tumor.

Source of Specimen(s):
Left Thigh Tumor

Gross Description:
Received in one part.
Source of Tissue: 1. Labeled # 1, "Left thigh tumor".

Frozen Section Diagnosis: 1FS-TUMOR IS UP TO THE FASCIA
(CIRCUMFERENTIAL).
THE PROXIMAL AND DISTAL MARGINS ARE GROSSLY NEGATIVE. DEFECT
NOTED IS
NOT REAL ACCORDING TO PER

Gross Description: Received fresh in a container labeled with patient's name and medical record number labeled "left thigh tumor". It consists of a roughly ovoid soft to rubbery mass measuring 26 x 14 x 12 cm. There is a stitch marking distal as per surgeon. At the deep aspect there is some overlying fascia and, there is a 1.5 x 1.5 cm ragged defect exposing of what appears to be tumor. This area is adjacent to some retractive fascia and is not a true defect as per Distally, there is skeletal muscle measuring up to 5.3 cm that is normal appearing. Sections disclose a 15 x 12.5 x 8.5 cm tumor. The more superficial aspect of the tumor is thinly capsulated with no defects or masses. Sections disclose predominately a soft yellow necrotic tumor and some hemorrhage more proximally. Towards the periphery and more distally there is a pink viable tumor noted. Fresh tissue is prepared for

Representative sections are submitted in 1A-1I as follows: 1A proximal, 1B distal, 1C-1D deep, 1E-1F superficial, 1G-1I additional sections of the tumor-no margins.

Summary of Sections: Representative sections are submitted in 1A-1I.

ICD-O-3
NOS
Leiomyosarcoma 8890/3
Site path
Connective subcutaneous
and other soft tissues
of thigh C49.2
C49.9
Connective subcutaneous
and other soft tissues NOS
C49.9
JW 5/24/13

Dual/Synchronous Primary (Noted)		

[page 2 of 2]
Final Diagnosis:

1) Left thigh tumor:

- Pleomorphic, high grade, spindle and giant cell leiomyosarcoma (15 cm).
- Tumor is present less than 1 mm from the superficial margin and within 1mm from the deep margin, see note.

Note: The 1 mm deep margin is dense collagenous tissue consistent with fascia. Immunohistochemical studies performed on the morphologically similar previous biopsy specimen by the referring laboratory reveal that the tumor is strongly and diffusely positive for smooth muscle actin and Vimentin and focally positive for muscle specific actin supporting the diagnosis of leiomyosarcoma.

Procedures/Addenda

Cytogenetics Solid Tumor Date Ordered:
Status
Date Complete By:
Date Reported

Results-Comments

CYTOGENETIC ANALYSIS REPORTS

TESTING CENTER:

DIAGNOSIS: Leiomyosarcoma

KARYOTYPE: Highly complex abnormal male karyotype with double minutes.

RESULTS: The tumor specimen was placed in culture and harvested after seven and twelve days. All eleven metaphases examined from the seven-day culture were abnormal and exhibited tremendous heterogeneity and complexity. Chromosome numbers ranged from 42 to 201, and every chromosome pair had a rearrangement. There were several clonal abnormalities that could not be definitively described as well as double minutes present in each cell. All ten cells from the twelve-day culture were apparently normal and presumably represent an outgrowth of normal cells from the tumor sample. A preliminary report was given to

Source: NCI Genomic Data Commons file b899e200-3874-4360-8b83-91afcab51759 (TCGA-PC-A5DM.DC2D49A5-961F-4806-81B8-C9AB50BD7810.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).